FM case AD7060 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Gallbladder.
https://portal.gdc.cancer.gov/cases/2d7c3669-80cd-4764-82d2-02e157b27b4f

Female, 48.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the gallbladder; primary biopsied or resected from the gallbladder. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
